Somatic mutation profile of tumor specimen C3L-06774-03 (aliquot CPT0422340006) from CPTAC case C3L-06774, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 47.7 years (17,414 days).
Specimen C3L-06774-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 740383a2-3ae4-46bd-a66b-7dabe8b6c32f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06774-31 (Blood Derived Normal), aliquot CPT0422330005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed03a2ef-6219-4d95-a2a4-0388da07cc80

The open-access MAF lists 1,060 somatic variants for this specimen: 812 protein-altering or splice-affecting, 209 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 777, Silent 209, Intron 28, Splice Region 13, Nonsense Mutation 12, Splice Site 5, 3'UTR 5, RNA 2, 3'Flank 2, Nonstop Mutation 2, IGR 1, Frame Shift Del 1.

Variants (750 of 1,060; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1923A>C p.K641N (on ENST00000288602 / NM_001374244.1; = p.K601N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/349 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs121913365, COSV56057324, COSV56058093, COSV56255469; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSBG2 | c.1235T>G p.L412W | Missense Mutation (SNP) | VAF 22/518 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs957679746; called by muse, mutect2
- ADGRV1 | c.3908T>C p.L1303S | Missense Mutation (SNP) | VAF 68/484 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67987145; called by muse, varscan2
- ADRB2 | c.1121A>G p.N374S | Missense Mutation (SNP) | VAF 28/540 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1308428481; called by muse, mutect2
- AKAP1 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 42/652 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs746420376; called by muse, mutect2
- ANKFN1 | c.399G>A p.V133= | Splice Region (SNP) | VAF 16/292 reads (5%) | catalogued as rs1193418999; called by muse, mutect2
- ASPDH | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 57/499 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as rs539778691; called by muse, mutect2, varscan2
- ATF7IP | c.3514C>T p.Q1172* | Nonsense Mutation (SNP) | VAF 22/530 reads (4%) | catalogued as rs1425002996, COSV53769135; called by muse, mutect2
- ATM | c.3878A>T p.N1293I | Missense Mutation (SNP) | VAF 19/370 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV53744275; called by muse, mutect2
- ATP1A1 | c.2531T>C p.L844P | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55194453; called by muse, mutect2
- ATP6V1H | c.388T>G p.L130V | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV100778760; called by muse, mutect2
- ATRN | c.3197A>C p.N1066T | Missense Mutation (SNP) | VAF 26/397 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53535209; called by muse, mutect2
- BNC2 | c.2071T>G p.F691V | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV66155230; called by muse, mutect2
- C16orf89 | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 60/455 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as rs1401604880; called by muse, mutect2, varscan2
- C1QTNF2 | c.638A>C p.K213T (on ENST00000393975; = p.K168T on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/546 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101220824; called by muse, mutect2
- CAPN11 | c.1590A>T p.R530S | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1464311303; called by muse, mutect2
- CARD6 | c.1784T>G p.I595S | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as COSV54565143; called by muse, mutect2
- CCDC151 | c.1076T>G p.F359C | Missense Mutation (SNP) | VAF 35/398 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1364394004; called by muse, mutect2
- CCDC169 | c.197T>G p.L66R | Missense Mutation (SNP) | VAF 28/287 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV53483722, COSV99521423; called by muse, mutect2, varscan2
- CD69 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 26/616 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as COSV57303924; called by muse, mutect2
- CDADC1 | c.1483A>T p.R495* | Nonsense Mutation (SNP) | VAF 16/450 reads (4%) | catalogued as COSV51911567; called by muse, mutect2
- CDC42BPA | c.1580T>G p.F527C | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV62014891; called by muse, mutect2
- CDC5L | c.1731A>C p.K577N | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV65176625; called by muse, mutect2, varscan2
- CDH1 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 47/401 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780537, CM070661, COSV55729844, COSV55741597; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CETN1 | c.44A>G p.Q15R | Missense Mutation (SNP) | VAF 33/398 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV59121867; called by muse, mutect2
- CFAP206 | c.558A>C p.E186D | Missense Mutation (SNP) | VAF 42/491 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.267); catalogued as COSV99739867; called by muse, mutect2
- COX5B | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 48/344 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as rs1325321877; called by muse, mutect2, varscan2
- CPLANE2 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 83/536 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as rs746095494; called by muse, mutect2, varscan2
- CRNN | c.538A>C p.S180R | Missense Mutation (SNP) | VAF 24/594 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV55122877; called by muse, mutect2
- CRYBG2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 47/354 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs373673197; called by muse, mutect2, varscan2
- CSMD1 | c.9361A>C p.S3121R (on ENST00000520002; = p.S3120R on NM_033225.6) | Missense Mutation (SNP) | VAF 50/429 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV59278385, COSV59291937; called by mutect2, varscan2
- CSNK2A1 | c.231A>C p.K77N | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53936225; called by muse, mutect2
- CTTNBP2 | c.1799A>T p.E600V | Missense Mutation (SNP) | VAF 24/600 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1563010320; called by muse, mutect2
- CYP4F3 | c.508A>C p.S170R | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55408917; called by muse, mutect2
- CYP4V2 | c.1015A>C p.N339H | Missense Mutation (SNP) | VAF 55/449 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV66507772; called by muse, mutect2, varscan2
- DCAF1 | c.3278A>G p.E1093G | Missense Mutation (SNP) | VAF 34/442 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.171); catalogued as rs1442928752; called by muse, mutect2
- DENND2A | c.1187A>C p.K396T | Missense Mutation (SNP) | VAF 23/539 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV52059226; called by muse, mutect2
- DLGAP4 | c.2792A>G p.K931R (on ENST00000339266 / NM_001365621.1; = p.K928R on NM_014902.6) | Missense Mutation (SNP) | VAF 33/476 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs1300183447; called by muse, mutect2
- DNAH10 | c.4654T>G p.F1552V (on ENST00000409039; = p.F1491V on NM_207437.3) | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745733999; called by muse, mutect2, varscan2
- DNAH5 | c.13685A>G p.E4562G | Missense Mutation (SNP) | VAF 55/450 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV99444035; called by muse, mutect2, varscan2
- DNMT3B | c.1742T>G p.F581C | Missense Mutation (SNP) | VAF 42/542 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52416716; called by muse, mutect2
- DTX1 | c.1163A>G p.K388R | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99986377; called by muse, mutect2
- DYNC2I1 | c.2656A>G p.S886G | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs777707290; called by muse, mutect2, varscan2
- EXOC6B | c.2381T>A p.L794H | Missense Mutation (SNP) | VAF 50/417 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99724681; called by muse, mutect2, varscan2
- EYS | c.2938A>T p.N980Y | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.36); catalogued as COSV65523720; called by muse, mutect2
- FAM178B | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs979767169; called by muse, varscan2
- FAT2 | c.4546T>C p.S1516P | Missense Mutation (SNP) | VAF 34/474 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs1325356034; called by muse, mutect2
- FBH1 | c.620A>G p.E207G (on ENST00000362091 / NM_178150.3; = p.E258G on NM_032807.4) | Missense Mutation (SNP) | VAF 26/535 reads (5%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.527); catalogued as COSV100758791; called by muse, mutect2
- FES | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.174); catalogued as rs763115607; called by muse, mutect2, varscan2
- FLG | c.2599T>C p.S867P | Missense Mutation (SNP) | VAF 89/605 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs1473159118; called by muse, mutect2, varscan2
- FOXD3 | c.248A>G p.K83R | Missense Mutation (SNP) | VAF 54/461 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs757514754; called by muse, mutect2, varscan2
- GCM2 | c.962A>G p.E321G | Missense Mutation (SNP) | VAF 63/468 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs775663970; called by muse, mutect2, varscan2
- GFI1B | c.752A>G p.Q251R | Missense Mutation (SNP) | VAF 30/622 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1302101616; called by muse, mutect2
- GOLGB1 | c.1311T>G p.F437L | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.044); catalogued as rs1227166662; called by muse, varscan2
- HECA | c.1602T>G p.F534L | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.979); catalogued as rs1208486153; called by muse, mutect2
- HOXD12 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 56/356 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1315835815; called by muse, mutect2, varscan2
- HSPA2 | c.1393A>G p.T465A | Missense Mutation (SNP) | VAF 38/478 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs993212121; called by muse, mutect2
- IDH3G | c.221A>T p.K74M | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54206408; called by muse, mutect2
- IGF2R | c.5449T>G p.L1817V | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63631968; called by muse, mutect2
- IGHV3-13 | c.163T>C p.W55R | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.763); catalogued as rs782653186; called by muse, mutect2
- IGLV1-36 | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 68/562 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); catalogued as rs775115985; called by muse, mutect2, varscan2
- KCNQ1 | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 63/452 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199472733, CM097181; ClinVar: not provided; called by muse, mutect2, varscan2
- KIF15 | c.983T>C p.L328P | Missense Mutation (SNP) | VAF 44/310 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261824614; called by muse, mutect2, varscan2
- KIZ | c.959T>C p.V320A | Missense Mutation (SNP) | VAF 122/564 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs1258363809, COSV55684045; called by muse, mutect2, varscan2
- KLHL20 | c.1198A>G p.S400G | Missense Mutation (SNP) | VAF 61/517 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.206); catalogued as rs768486208; called by muse, mutect2, varscan2
- KLHL20 | c.1544G>A p.R515K | Missense Mutation (SNP) | VAF 23/534 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV52942736; called by muse, mutect2
- LEXM | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 54/461 reads (12%) | catalogued as rs770603510, COSV64024402; called by muse, mutect2, varscan2
- LRP1B | c.10240T>G p.L3414V | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.484); catalogued as COSV67263549; called by muse, mutect2, varscan2
- MACROD2 | c.210A>C p.E70D | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1380457047; called by muse, mutect2
- MAN2B2 | c.1204T>C p.W402R | Missense Mutation (SNP) | VAF 38/592 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.877); catalogued as rs1392718720; called by muse, mutect2
- MCM8 | c.1223A>G p.N408S | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs1028663842; called by muse, mutect2, varscan2
- MGAT4A | c.594A>C p.K198N | Missense Mutation (SNP) | VAF 27/283 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.055); catalogued as rs1183412661; called by muse, mutect2
- MROH7 | c.2281C>T p.R761W | Missense Mutation (SNP) | VAF 62/496 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781718343; called by muse, mutect2, varscan2
- MUC4 | c.12445A>G p.I4149V | Missense Mutation (SNP) | VAF 40/782 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.364); catalogued as rs1206937393, COSV100204820; called by muse, mutect2
- MYT1 | c.1601A>C p.K534T | Missense Mutation (SNP) | VAF 24/662 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV60501035; called by muse, mutect2
- NCKAP5L | c.1604T>G p.L535R | Missense Mutation (SNP) | VAF 42/709 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.851); catalogued as COSV100259008; called by muse, mutect2
- NOX1 | c.1568A>G p.K523R | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs376041993; called by mutect2, varscan2
- NUP205 | c.5734T>A p.L1912M | Missense Mutation (SNP) | VAF 25/517 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV53657767; called by muse, mutect2
- NUTM1 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV61546825; called by muse, mutect2
- OR51A7 | c.75T>G p.I25M | Missense Mutation (SNP) | VAF 71/438 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as COSV63788496, COSV63788793; called by muse, mutect2, varscan2
- OR52A1 | c.232A>G p.S78G | Missense Mutation (SNP) | VAF 62/406 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1419474527; called by muse, mutect2, varscan2
- OR5L2 | c.665T>G p.L222R | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65723346; called by muse, mutect2, varscan2
- OR6T1 | c.955A>G p.T319A | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.026); catalogued as rs746714272; called by muse, mutect2, varscan2
- OR8J3 | c.626T>G p.F209C | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV56883409; called by muse, mutect2, varscan2
- OTOP3 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 61/480 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751666796; called by muse, mutect2, varscan2
- PACSIN1 | c.917A>G p.N306S | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.908); catalogued as rs1372248546; called by muse, mutect2
- PDS5B | c.3460A>G p.T1154A | Missense Mutation (SNP) | VAF 50/538 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as rs1268218734; called by muse, mutect2
- PRICKLE1 | c.1076A>C p.K359T | Missense Mutation (SNP) | VAF 42/606 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.257); catalogued as COSV100566712; called by muse, mutect2
- PTCH1 | c.2657T>C p.L886P | Missense Mutation (SNP) | VAF 36/550 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV100109889; called by muse, mutect2
- RIF1 | c.3480A>C p.K1160N | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV104388400; called by muse, mutect2
- RIMBP2 | c.3037T>G p.F1013V | Missense Mutation (SNP) | VAF 56/395 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55466023, COSV55470989, COSV55480263; called by muse, mutect2, varscan2
- RIMS2 | c.1510G>A p.G504S (on ENST00000666250 / NM_001348490.2; = p.G312S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/464 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs200408676; called by muse, mutect2, varscan2
- RRH | c.319T>G p.F107V | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1246232175; called by mutect2, varscan2
- RUFY3 | c.1858T>C p.S620P | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV66814103; called by muse, mutect2, varscan2
- SAMD11 | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs1476899771; called by muse, mutect2
- SAMD9L | c.3203A>C p.E1068A | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.356); catalogued as COSV59083344; called by muse, mutect2
- SBF1 | c.197T>C p.F66S | Missense Mutation (SNP) | VAF 17/431 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1233471028, COSV62370154; called by muse, mutect2
- SCUBE3 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201803545; called by muse, mutect2, varscan2
- SF3B1 | c.893A>C p.K298T | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV59216515; called by muse, mutect2, varscan2
- SH3KBP1 | c.1205A>C p.K402T | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1296872570; called by muse, mutect2, varscan2
- SLC39A6 | c.658A>G p.S220G | Missense Mutation (SNP) | VAF 46/548 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1215977423; called by muse, mutect2
- SMR3A | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 61/465 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs1047186292; called by muse, mutect2, varscan2
- SPATC1L | c.441G>T p.K147N | Missense Mutation (SNP) | VAF 97/675 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99386113; called by muse, mutect2, varscan2
- SPTY2D1OS | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 63/439 reads (14%) | PolyPhen possibly damaging (0.81); catalogued as rs924077738; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.974T>G p.L325R | Missense Mutation (SNP) | VAF 36/316 reads (11%) | PolyPhen benign (0.068); catalogued as rs1459040027; called by muse, mutect2, varscan2
- TAOK3 | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1227433523, COSV101183718; called by muse, mutect2
- TET1 | c.3986T>G p.L1329R | Missense Mutation (SNP) | VAF 55/467 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV101019121; called by muse, mutect2, varscan2
- TEX2 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 23/556 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV99366788; called by muse, mutect2
- TLL2 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs372575861; called by muse, mutect2
- TMEM131 | c.1147A>C p.S383R | Missense Mutation (SNP) | VAF 19/356 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.541); catalogued as COSV51773363; called by muse, mutect2
- TRIM6-TRIM34 | c.1379T>C p.L460P | Missense Mutation (SNP) | VAF 33/435 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1179623588; called by muse, mutect2
- TTN | c.41495T>C p.L13832P (on ENST00000591111; = p.L6408P on NM_003319.4) | Missense Mutation (SNP) | VAF 14/266 reads (5%) | PolyPhen probably damaging (0.999); catalogued as COSV100590614, COSV100594174; called by muse, mutect2
- TTN | c.35751A>C p.E11917D (on ENST00000591111; = p.E4493D on NM_003319.4) | Missense Mutation (SNP) | VAF 16/286 reads (6%) | PolyPhen benign (0.325); catalogued as COSV60050738; called by muse, mutect2
- UST | c.172T>C p.F58L | Missense Mutation (SNP) | VAF 43/556 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1164895344; called by muse, mutect2
- WDR55 | c.626A>G p.Q209R | Missense Mutation (SNP) | VAF 30/546 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as rs972105860; called by muse, mutect2
- XPO7 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs773722282; called by muse, varscan2
- ZNF16 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 60/440 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs749617767; called by muse, varscan2
- ZNF41 | c.1328A>G p.D443G | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs993919615; called by muse, mutect2, varscan2
- ZNF558 | c.63A>C p.Q21H | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.146); catalogued as rs764281297, COSV56864412; called by mutect2, varscan2
- ZNF644 | c.3332T>C p.L1111P | Missense Mutation (SNP) | VAF 48/318 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV61348895; called by muse, mutect2, varscan2
- ZNF737 | c.647T>G p.L216R | Missense Mutation (SNP) | VAF 30/526 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs376730159; called by muse, mutect2
- ZSCAN18 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 47/293 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.057); catalogued as rs1444689593; called by muse, mutect2, varscan2
- ZSCAN20 | c.1647A>C p.K549N | Missense Mutation (SNP) | VAF 74/523 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792497; called by muse, mutect2, varscan2
- ZSWIM8 | c.3008A>G p.K1003R (on ENST00000605216 / NM_001242487.2; = p.K1008R on NM_015037.3) | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs1259316379; called by muse, mutect2
- A1CF | c.91T>G p.L31V | Missense Mutation (SNP) | VAF 39/341 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- AADACL3 | c.1034A>G p.E345G | Missense Mutation (SNP) | VAF 24/558 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2
- AARS1 | c.1535A>T p.E512V | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.172); called by muse, mutect2
- AATF | c.263A>C p.Q88P | Missense Mutation (SNP) | VAF 54/412 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ABCA1 | c.5918A>C p.N1973T | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.071); called by muse, mutect2
- ABCA10 | c.90A>C p.K30N | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2
- ABCA13 | c.14959T>G p.L4987V | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ABCA4 | c.2002T>A p.S668T | Missense Mutation (SNP) | VAF 28/528 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.298); called by muse, mutect2
- ABCA8 | c.2092T>G p.L698V | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- ABCC2 | c.1408A>C p.M470L | Missense Mutation (SNP) | VAF 43/511 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2
- ABCC5 | c.591+4A>G | Splice Region (SNP) | VAF 34/658 reads (5%) | called by muse, mutect2
- ACO1 | c.262T>C p.F88L | Missense Mutation (SNP) | VAF 14/323 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); called by muse, mutect2
- ACSM3 | c.1122A>C p.E374D | Missense Mutation (SNP) | VAF 24/333 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.917); called by muse, mutect2
- ACVR2B | c.322T>G p.F108V | Missense Mutation (SNP) | VAF 45/342 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ADAM33 | c.727T>C p.Y243H | Missense Mutation (SNP) | VAF 21/536 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); called by muse, mutect2
- ADAMTS14 | c.2323A>G p.S775G | Missense Mutation (SNP) | VAF 20/525 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); called by muse, mutect2
- ADCY7 | c.3104A>T p.E1035V | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ADGRB3 | c.3864T>G p.N1288K | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ADGRG6 | c.1798A>T p.N600Y | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- ADGRV1 | c.3874T>G p.F1292V | Missense Mutation (SNP) | VAF 56/466 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); called by muse, varscan2
- ADH7 | c.961T>G p.F321V | Missense Mutation (SNP) | VAF 28/498 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.212); called by muse, mutect2
- ADSL | c.303A>C p.K101N | Missense Mutation (SNP) | VAF 28/588 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.752); called by muse, mutect2
- AFF4 | c.703A>C p.T235P | Missense Mutation (SNP) | VAF 26/482 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.071); called by muse, mutect2
- AFP | c.991A>C p.N331H | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2
- AGBL5 | c.2250T>G p.S750R | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AHCTF1 | c.1534T>G p.F512V (on ENST00000366508; = p.F486V on NM_015446.5) | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AJUBA | c.1085A>T p.Q362L | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.137); called by muse, mutect2
- AKAP1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 30/528 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- AKAP13 | c.7112A>C p.K2371T (on ENST00000394518 / NM_007200.5; = p.K2375T on NM_006738.6) | Missense Mutation (SNP) | VAF 60/327 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKAP6 | c.1509A>C p.E503D | Missense Mutation (SNP) | VAF 23/506 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- AKR1C1 | c.601A>C p.K201Q | Missense Mutation (SNP) | VAF 29/577 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.244); called by muse, mutect2
- ALDH8A1 | c.52T>G p.F18V | Missense Mutation (SNP) | VAF 40/404 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ALG11 | c.992T>G p.V331G | Missense Mutation (SNP) | VAF 50/888 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- AMIGO2 | c.938A>T p.K313M | Missense Mutation (SNP) | VAF 59/416 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- AMPD1 | c.1927T>G p.L643V | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANK2 | c.9837A>C p.E3279D | Missense Mutation (SNP) | VAF 61/359 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ANKRD17 | c.1265A>C p.E422A | Missense Mutation (SNP) | VAF 17/358 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); called by muse, mutect2
- ANKRD30B | c.2787A>C p.K929N | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.607); called by muse, mutect2
- ANKRD31 | c.2481A>C p.E827D | Missense Mutation (SNP) | VAF 45/269 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ANO8 | c.1894A>T p.S632C | Missense Mutation (SNP) | VAF 51/644 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ANOS1 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANXA3 | c.693A>C p.E231D | Missense Mutation (SNP) | VAF 38/300 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AOAH | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 62/653 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- APC | c.7160A>C p.N2387T | Missense Mutation (SNP) | VAF 33/504 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2
- AQR | c.3508A>C p.N1170H | Missense Mutation (SNP) | VAF 19/505 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AREL1 | c.2141A>C p.D714A | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARFIP1 | c.437A>G p.K146R (on ENST00000353617 / NM_001287432.1; = p.K114R on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.013); called by muse, mutect2
- ARG1 | c.458A>C p.K153T | Missense Mutation (SNP) | VAF 23/325 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2
- ARHGAP33 | c.1546T>G p.S516A | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.147); called by muse, mutect2
- ARHGAP42 | c.2269T>G p.L757V | Missense Mutation (SNP) | VAF 24/417 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.967); called by muse, mutect2
- ARHGEF11 | c.2537A>C p.K846T | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- ARID4B | c.1700A>C p.E567A | Missense Mutation (SNP) | VAF 48/611 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ARNT | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 58/482 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASIC5 | c.308A>C p.K103T | Missense Mutation (SNP) | VAF 31/473 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.156); called by muse, mutect2
- ATP11A | c.1229A>G p.Y410C | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ATP12A | c.2981T>C p.L994S | Missense Mutation (SNP) | VAF 47/479 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- ATP1A1 | c.863T>G p.I288S | Missense Mutation (SNP) | VAF 35/691 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ATP2C2 | c.2345A>G p.E782G | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2
- ATXN1L | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 36/599 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- BCAR3 | c.1382A>G p.K461R | Missense Mutation (SNP) | VAF 28/542 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- BCL2A1 | c.479T>G p.V160G | Missense Mutation (SNP) | VAF 31/440 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2
- BCOR | c.4646T>G p.L1549R (on ENST00000378444 / NM_001123385.2; = p.L1515R on NM_017745.6) | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCORL1 | c.3389A>G p.Q1130R | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BDP1 | c.6501A>C p.K2167N | Missense Mutation (SNP) | VAF 72/525 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BEND3 | c.1439T>C p.L480P | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BIRC6 | c.2093T>G p.L698R | Missense Mutation (SNP) | VAF 59/446 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BMS1 | c.3065A>C p.K1022T | Missense Mutation (SNP) | VAF 19/269 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.006); called by muse, mutect2
- BMX | c.1675A>C p.R559= | Splice Region (SNP) | VAF 59/198 reads (30%) | called by muse, mutect2, varscan2
- BOD1L2 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 18/562 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2
- BPIFB2 | c.1142T>C p.V381A | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- BPTF | c.1112T>G p.F371C | Missense Mutation (SNP) | VAF 33/462 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BRD7 | c.557A>C p.K186T | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- BSN | c.6233A>G p.D2078G | Missense Mutation (SNP) | VAF 22/600 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.287); called by muse, mutect2
- BTBD8 | c.3542A>C p.D1181A (on ENST00000636805 / NM_001376131.1; = p.D668A on NM_015237.4) | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2
- BTBD9 | c.1339T>A p.L447M | Missense Mutation (SNP) | VAF 53/385 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTN2A1 | c.815T>C p.L272P | Missense Mutation (SNP) | VAF 25/465 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2
- BTN3A1 | c.548A>T p.K183M | Missense Mutation (SNP) | VAF 35/718 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); called by muse, mutect2
- BTN3A3 | c.383T>C p.F128S | Missense Mutation (SNP) | VAF 62/493 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C10orf105 | c.164T>C p.F55S | Missense Mutation (SNP) | VAF 42/642 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- C2CD3 | c.2096A>G p.E699G | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2
- C4orf46 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.334); called by muse, mutect2
- C5AR1 | c.760T>C p.F254L | Missense Mutation (SNP) | VAF 73/488 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C8B | c.763A>C p.S255R | Missense Mutation (SNP) | VAF 45/398 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CACNA1E | c.3134T>C p.V1045A | Missense Mutation (SNP) | VAF 36/600 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- CACNA1E | c.4563T>G p.F1521L | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- CACNA1S | c.2345T>A p.F782Y | Missense Mutation (SNP) | VAF 42/450 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CACNA2D3 | c.1859T>A p.L620H | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CACNA2D4 | c.584T>G p.F195C | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CACNG2 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 24/578 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- CAMKK2 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 24/408 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2
- CAND1 | c.1984A>C p.N662H | Missense Mutation (SNP) | VAF 30/496 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CARMIL1 | c.3236A>C p.K1079T | Missense Mutation (SNP) | VAF 38/552 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); called by muse, mutect2
- CARMIL1 | c.3440A>G p.D1147G | Missense Mutation (SNP) | VAF 74/500 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CASKIN1 | c.4237G>A p.D1413N | Missense Mutation (SNP) | VAF 56/411 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- CBL | c.492A>C p.E164D | Missense Mutation (SNP) | VAF 17/444 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); called by muse, mutect2
- CC2D2B | c.486A>C p.E162D (on ENST00000646931 / NM_001349008.3; = p.E154D on NM_001130446.3) | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CCAR1 | c.659T>C p.L220P | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC113 | c.482A>C p.K161T | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2
- CCDC168 | c.19247T>G p.L6416R | Missense Mutation (SNP) | VAF 90/446 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC168 | c.6668A>C p.K2223T | Missense Mutation (SNP) | VAF 44/554 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.318); called by muse, mutect2
- CCDC68 | c.605A>C p.K202T | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CCDC81 | c.493T>G p.F165V | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CCR5 | c.965A>C p.K322T | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- CCSER1 | c.764A>G p.Q255R | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.578); called by muse, mutect2
- CD1D | c.139T>G p.L47V | Missense Mutation (SNP) | VAF 92/510 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CD53 | c.613A>C p.T205P | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- CDC16 | c.803T>C p.L268S | Missense Mutation (SNP) | VAF 30/477 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDH23 | c.1055A>G p.E352G | Missense Mutation (SNP) | VAF 30/505 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); called by muse, mutect2
- CDK11B | c.1072A>G p.S358G | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- CDK13 | c.1754A>C p.K585T | Missense Mutation (SNP) | VAF 56/405 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CDKL2 | c.1331A>G p.E444G | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- CDKL4 | c.743T>C p.L248P | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CDO1 | c.359A>C p.K120T | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.055); called by muse, mutect2
- CENPF | c.1526T>G p.L509R | Missense Mutation (SNP) | VAF 36/551 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CENPJ | c.1563A>C p.Q521H | Missense Mutation (SNP) | VAF 22/710 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2
- CEP126 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 26/411 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.652); called by muse, mutect2
- CEP290 | c.3771A>T p.R1257S | Missense Mutation (SNP) | VAF 39/546 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- CEP295 | c.2882A>C p.K961T | Missense Mutation (SNP) | VAF 25/490 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2
- CEP44 | c.616T>G p.L206V | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP57 | c.738A>C p.E246D | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- CEP85 | c.1775A>G p.Q592R | Missense Mutation (SNP) | VAF 26/520 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.066); called by muse, mutect2
- CFAP61 | c.1391T>G p.I464S | Missense Mutation (SNP) | VAF 13/345 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- CFAP65 | c.5150A>G p.K1717R | Missense Mutation (SNP) | VAF 23/531 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CFAP65 | c.3011T>C p.V1004A | Missense Mutation (SNP) | VAF 59/375 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- CGRRF1 | c.447A>C p.E149D | Missense Mutation (SNP) | VAF 9/238 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2
- CHD9 | c.3610T>G p.F1204V | Missense Mutation (SNP) | VAF 24/437 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- CHN1 | c.1277T>G p.L426R | Missense Mutation (SNP) | VAF 60/420 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CHST12 | c.1099A>G p.S367G | Missense Mutation (SNP) | VAF 40/692 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.117); called by muse, mutect2
- CKMT1B | c.1006A>G p.S336G | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.132); called by muse, mutect2
- CLUH | c.2530T>C p.F844L (on ENST00000435359; = p.F883L on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/371 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CNGA1 | c.1994T>G p.L665R | Missense Mutation (SNP) | VAF 30/473 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.078); called by muse, mutect2
- CNOT2 | c.532A>C p.K178Q | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2
- CNOT6 | c.439A>T p.R147* | Nonsense Mutation (SNP) | VAF 28/433 reads (6%) | called by muse, mutect2
- CNOT6 | c.504A>C p.Q168H | Missense Mutation (SNP) | VAF 43/429 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2
- CNRIP1 | c.275A>G p.E92G | Missense Mutation (SNP) | VAF 45/662 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); called by muse, mutect2
- CNTLN | c.1314A>T p.Q438H | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- CNTN1 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.059); called by muse, mutect2
- COL15A1 | c.3874T>C p.S1292P | Missense Mutation (SNP) | VAF 24/397 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2
- COL20A1 | c.2897T>C p.F966S | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL24A1 | c.4957A>C p.N1653H | Missense Mutation (SNP) | VAF 30/503 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2
- COL27A1 | c.4928T>A p.L1643H | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- COL5A1 | c.2944G>T p.G982C | Missense Mutation (SNP) | VAF 35/540 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL6A6 | c.2372T>C p.L791P | Missense Mutation (SNP) | VAF 42/361 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COPA | c.2411T>G p.L804W | Missense Mutation (SNP) | VAF 51/381 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- COPB2 | c.1252T>G p.F418V | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- COX7A2L | c.171A>C p.K57N | Missense Mutation (SNP) | VAF 33/631 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- CPLANE1 | c.9383A>C p.K3128T | Missense Mutation (SNP) | VAF 40/476 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- CPLX4 | c.403T>G p.L135V | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.079); called by muse, mutect2
- CPQ | c.752A>C p.K251T | Missense Mutation (SNP) | VAF 59/497 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- CRACDL | c.2486T>A p.V829D | Missense Mutation (SNP) | VAF 32/608 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2
- CRYBB1 | c.727T>C p.F243L | Missense Mutation (SNP) | VAF 20/494 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- CSRNP3 | c.824T>G p.L275R | Missense Mutation (SNP) | VAF 46/407 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTAGE1 | c.377A>C p.K126T | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- CTDP1 | c.2075A>G p.E692G | Missense Mutation (SNP) | VAF 20/496 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTNNA1 | c.2666A>C p.K889T | Missense Mutation (SNP) | VAF 23/413 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2
- CTNND1 | c.677A>T p.D226V | Missense Mutation (SNP) | VAF 32/606 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2
- CYLD | c.1054T>G p.S352A | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); called by muse, mutect2
- CYP2C9 | c.608A>G p.E203G | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CYP4F12 | c.1343A>G p.E448G | Missense Mutation (SNP) | VAF 30/313 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.251); called by muse, mutect2
- CYP4V2 | c.1433A>C p.K478T | Missense Mutation (SNP) | VAF 28/424 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DAPK3 | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DBF4 | c.502A>C p.K168Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCAF1 | c.3499A>C p.K1167Q | Missense Mutation (SNP) | VAF 24/395 reads (6%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.662); called by muse, mutect2
- DDX58 | c.2135T>G p.V712G | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DENND1B | c.1776T>G p.D592E | Missense Mutation (SNP) | VAF 16/277 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.279); called by muse, mutect2
- DENND4C | c.2398C>T p.L800F | Missense Mutation (SNP) | VAF 22/395 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DENND4C | c.5780dup p.S1928Vfs*6 (on ENST00000434457 / NM_001330640.2; = p.S1879Vfs*6 on NM_017925.7) | Frame Shift Ins (INS) | VAF 40/391 reads (10%) | called by mutect2, pindel, varscan2
- DENND5B | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 27/474 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2
- DEPDC1 | c.1219A>C p.S407R | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- DGKI | c.1895A>C p.Q632P | Missense Mutation (SNP) | VAF 32/492 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2
- DIP2B | c.2497T>G p.L833V | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DIP2C | c.1561T>C p.C521R | Missense Mutation (SNP) | VAF 49/295 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- DLG2 | c.431T>C p.L144P | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- DLGAP5 | c.889A>C p.N297H | Missense Mutation (SNP) | VAF 22/399 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- DNAAF3 | c.328A>C p.S110R (on ENST00000524407 / NM_001256715.2; = p.S157R on NM_178837.4) | Missense Mutation (SNP) | VAF 22/558 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); called by muse, mutect2
- DNAH17 | c.11638T>A p.S3880T | Missense Mutation (SNP) | VAF 43/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH3 | c.10542T>A p.D3514E | Missense Mutation (SNP) | VAF 62/412 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.10814A>G p.E3605G | Missense Mutation (SNP) | VAF 38/489 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.99); called by muse, mutect2
- DNAJC6 | c.292T>G p.L98V | Missense Mutation (SNP) | VAF 52/463 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- DPYD | c.106T>G p.L36V | Missense Mutation (SNP) | VAF 21/364 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- DPYSL2 | c.512A>C p.K171T | Missense Mutation (SNP) | VAF 33/460 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.323); called by muse, mutect2
- DSC3 | c.1072A>C p.N358H | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2
- DSN1 | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 26/608 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DTL | c.332T>G p.L111R | Missense Mutation (SNP) | VAF 47/344 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- DUSP1 | c.611T>G p.I204S | Missense Mutation (SNP) | VAF 32/502 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- DUSP13 | c.62T>G p.I21S | Missense Mutation (SNP) | VAF 36/626 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.115); called by muse, mutect2
- DUSP4 | c.761A>G p.D254G | Missense Mutation (SNP) | VAF 22/367 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- EBF2 | c.1160A>C p.N387T | Missense Mutation (SNP) | VAF 61/458 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ECEL1 | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 35/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- ECI2 | c.212A>C p.Q71P (on ENST00000380118 / NM_206836.3; = p.Q41P on NM_006117.2) | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ECT2 | c.2140T>G p.F714V (on ENST00000392692 / NM_001349098.2; = p.F683V on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/426 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.218); called by muse, mutect2
- EDEM1 | c.1735A>T p.T579S | Missense Mutation (SNP) | VAF 37/552 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EEA1 | c.2779C>T p.H927Y | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2
- EEF1AKMT4-ECE2 | c.1592T>C p.L531P | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.958); called by muse, mutect2
- EGF | c.1892T>G p.L631R | Missense Mutation (SNP) | VAF 27/509 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.02); called by muse, mutect2
- EIF3M | c.279T>G p.F93L | Missense Mutation (SNP) | VAF 19/469 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0.025); called by muse, mutect2
- ELAPOR2 | c.1487T>G p.F496C (on ENST00000450689 / NM_001142749.3; = p.F329C on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ELMO2 | c.1061T>G p.F354C | Missense Mutation (SNP) | VAF 30/309 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EMILIN1 | c.1085T>C p.L362P | Missense Mutation (SNP) | VAF 22/536 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- EN1 | c.1019T>C p.L340P | Missense Mutation (SNP) | VAF 60/406 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB41L5 | c.1737A>C p.K579N | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EPG5 | c.1868T>G p.L623R | Missense Mutation (SNP) | VAF 26/640 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- ERN1 | c.1136T>G p.F379C | Missense Mutation (SNP) | VAF 32/483 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- ERVMER34-1 | c.1213A>C p.T405P | Missense Mutation (SNP) | VAF 28/480 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2
- ETV5 | c.1130T>G p.L377R | Missense Mutation (SNP) | VAF 22/549 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EXD2 | c.224T>G p.L75R | Missense Mutation (SNP) | VAF 44/514 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.288); called by muse, mutect2
- EXOC4 | c.2837A>C p.N946T | Missense Mutation (SNP) | VAF 97/455 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EXPH5 | c.125T>G p.L42R | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- EXTL1 | c.1373T>A p.L458H | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.158); called by muse, mutect2
- EXTL3 | c.247T>C p.C83R | Missense Mutation (SNP) | VAF 33/482 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.096); called by muse, mutect2
- FAM111A | c.596T>G p.V199G | Missense Mutation (SNP) | VAF 16/493 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- FAM217A | c.278A>C p.N93T | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.178); called by muse, mutect2
- FAM71F1 | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.054); called by muse, mutect2
- FAR2 | c.527A>C p.K176T | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- FAT2 | c.5786A>T p.N1929I | Missense Mutation (SNP) | VAF 18/429 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- FBN1 | c.3326A>C p.K1109T | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- FBP2 | c.986T>C p.L329P | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FBXO17 | c.241T>A p.C81S | Missense Mutation (SNP) | VAF 48/572 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2
- FBXO39 | c.1142T>G p.F381C | Missense Mutation (SNP) | VAF 33/491 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FBXO8 | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FFAR4 | c.431A>G p.Q144R | Missense Mutation (SNP) | VAF 28/616 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- FGFR1 | c.568T>C p.W190R (on ENST00000447712 / NM_023110.3; = p.W188R on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/535 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- FOCAD | c.4257T>G p.N1419K | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- FOXK1 | c.385T>C p.S129P | Missense Mutation (SNP) | VAF 50/438 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- FRMD5 | c.1216A>T p.R406* | Nonsense Mutation (SNP) | VAF 27/496 reads (5%) | called by muse, mutect2
- FRMD5 | c.928T>G p.L310V | Missense Mutation (SNP) | VAF 37/535 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- FSIP2 | c.8273A>G p.K2758R | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.497); called by muse, mutect2
- FSIP2 | c.8808T>G p.I2936M | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- GAB1 | c.1908A>C p.K636N | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GABRG3 | c.1173A>C p.L391F | Missense Mutation (SNP) | VAF 18/427 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.033); called by muse, mutect2
- GATA2 | c.1240T>C p.F414L | Missense Mutation (SNP) | VAF 55/623 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- GATAD2A | c.493T>G p.L165V | Missense Mutation (SNP) | VAF 30/528 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GCM1 | c.1031A>G p.E344G | Missense Mutation (SNP) | VAF 22/490 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.751); called by muse, mutect2
- GET1-SH3BGR | c.449T>G p.V150G | Missense Mutation (SNP) | VAF 38/485 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- GFY | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 72/480 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GGH | c.529T>C p.F177L | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2
- GJD4 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 64/439 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- GLB1L | c.1483A>C p.K495Q | Missense Mutation (SNP) | VAF 24/427 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- GLYATL1B | c.185A>G p.Q62R | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- GNL3L | c.1682A>G p.K561R | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GNPTAB | c.749A>C p.N250T | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGB1 | c.7490T>G p.L2497R | Missense Mutation (SNP) | VAF 29/503 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR107 | c.321T>G p.N107K | Missense Mutation (SNP) | VAF 15/355 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.079); called by muse, mutect2
- GPR108 | c.1010T>A p.L337Q (on ENST00000264080 / NM_001080452.1; = p.L95Q on NM_020171.2) | Missense Mutation (SNP) | VAF 51/377 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GPR153 | c.298T>C p.S100P | Missense Mutation (SNP) | VAF 47/506 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR155 | c.344T>C p.F115S | Missense Mutation (SNP) | VAF 18/468 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.253); called by muse, mutect2
- GPR33 | c.919A>C p.K307Q | Missense Mutation (SNP) | VAF 18/391 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.1); called by muse, mutect2
- GPRC6A | c.1851A>T p.R617S | Missense Mutation (SNP) | VAF 26/507 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.456); called by muse, mutect2
- GREB1 | c.1136A>C p.K379T | Missense Mutation (SNP) | VAF 45/368 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- GRID2 | c.922A>C p.T308P | Missense Mutation (SNP) | VAF 40/323 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GRIP1 | c.1297A>G p.S433G (on ENST00000359742 / NM_001379345.1; = p.S381G on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/474 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by muse, mutect2
- GTSE1 | c.2210T>A p.L737H | Missense Mutation (SNP) | VAF 54/417 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEATR5B | c.2522A>C p.K841T | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- HECTD4 | c.2246T>G p.L749R | Missense Mutation (SNP) | VAF 70/487 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HECW1 | c.4759T>G p.S1587A | Missense Mutation (SNP) | VAF 39/476 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.098); called by muse, mutect2
- HERC1 | c.13667A>T p.E4556V | Missense Mutation (SNP) | VAF 40/442 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2
- HFE | c.1006A>C p.R336= | Splice Region (SNP) | VAF 29/255 reads (11%) | called by muse, mutect2, varscan2
- HFM1 | c.1327A>T p.K443* | Nonsense Mutation (SNP) | VAF 34/343 reads (10%) | called by muse, mutect2, varscan2
- HIF3A | c.878-1G>A p.X293_splice (on ENST00000377670 / NM_152795.4; = p.X224_splice on NM_022462.4) | Splice Site (SNP) | VAF 56/350 reads (16%) | called by muse, mutect2, varscan2
- HJURP | c.1079T>G p.L360R | Missense Mutation (SNP) | VAF 35/617 reads (6%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.89); called by muse, mutect2
- HK1 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 45/357 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- HLCS | c.2003T>A p.V668D | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2
- HNRNPH3 | c.764A>C p.K255T | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HOOK1 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.208); called by muse, mutect2
- HOXA4 | c.868T>C p.S290P | Missense Mutation (SNP) | VAF 36/608 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- HOXA5 | c.650A>C p.N217T | Missense Mutation (SNP) | VAF 19/494 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HOXB13 | c.484T>A p.S162T | Missense Mutation (SNP) | VAF 34/618 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- HPR | c.343T>G p.F115V | Missense Mutation (SNP) | VAF 42/660 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2
- HPSE | c.1396T>G p.L466V | Missense Mutation (SNP) | VAF 20/443 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.129); called by muse, mutect2
- HPSE | c.979T>G p.F327V | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.046); called by muse, mutect2
- HPSE2 | c.472T>G p.L158V | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- HSD17B4 | c.2136A>T p.*712Cext*2 | Nonstop Mutation (SNP) | VAF 30/451 reads (7%) | called by muse, mutect2
- HSPA4L | c.1862A>G p.K621R | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); called by muse, mutect2
- HYKK | c.1018A>C p.T340P | Missense Mutation (SNP) | VAF 23/448 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2
- IARS2 | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 25/475 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2
- IGF1R | c.1103-1G>A p.X368_splice | Splice Site (SNP) | VAF 20/302 reads (7%) | called by muse, mutect2
- IGKV1-6 | c.230A>G p.Q77R | Missense Mutation (SNP) | VAF 43/648 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- IL1RAPL2 | c.577A>C p.I193L | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.014); called by muse, mutect2
- INSL4 | c.314A>C p.K105T | Missense Mutation (SNP) | VAF 20/453 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.334); called by muse, mutect2
- IPO13 | c.845T>G p.L282R | Missense Mutation (SNP) | VAF 44/339 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- IQCA1 | c.1128A>C p.K376N | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- IQCA1L | c.1967A>T p.K656M | Missense Mutation (SNP) | VAF 50/447 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IQCM | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 61/461 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ITFG1 | c.752A>G p.E251G | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- ITIH1 | c.917A>G p.Q306R | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2
- JAK2 | c.1083A>C p.E361D | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- JMJD1C | c.6320A>C p.N2107T | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- JMJD8 | c.754A>C p.N252H | Missense Mutation (SNP) | VAF 27/419 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KALRN | c.4670A>G p.K1557R | Missense Mutation (SNP) | VAF 54/339 reads (16%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KATNA1 | c.371A>C p.K124T | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.022); called by muse, mutect2
- KCNJ10 | c.911A>G p.E304G | Missense Mutation (SNP) | VAF 19/584 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNJ16 | c.1046A>G p.Q349R | Missense Mutation (SNP) | VAF 45/489 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2
- KCNV1 | c.118T>C p.C40R | Missense Mutation (SNP) | VAF 38/536 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2
- KCTD4 | c.274T>G p.F92V | Missense Mutation (SNP) | VAF 32/670 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- KDM1B | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 23/534 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA0319L | c.3011A>G p.E1004G | Missense Mutation (SNP) | VAF 32/457 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2
- KIAA0895L | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 40/502 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2
- KIAA0930 | c.607T>C p.F203L (on ENST00000336156 / NM_001009880.2; = p.F208L on NM_015264.2) | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2
- KIAA1217 | c.2381A>C p.K794T | Missense Mutation (SNP) | VAF 62/442 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIAA1549 | c.1838A>C p.E613A | Missense Mutation (SNP) | VAF 23/464 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2
- KIF13A | c.827A>C p.N276T | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- KIF20B | c.4155A>T p.E1385D (on ENST00000371728 / NM_001284259.2; = p.E1345D on NM_016195.4) | Missense Mutation (SNP) | VAF 62/300 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIN | c.1082A>C p.N361T | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KL | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 30/674 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- KL | c.2886T>A p.F962L | Missense Mutation (SNP) | VAF 26/605 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- KLF15 | c.536A>G p.K179R | Missense Mutation (SNP) | VAF 84/596 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, varscan2
- KLHL14 | c.605A>C p.K202T | Missense Mutation (SNP) | VAF 28/534 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.617); called by muse, mutect2
- KLHL5 | c.1017A>C p.K339N | Missense Mutation (SNP) | VAF 23/383 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.05); called by muse, mutect2
- KMT2C | c.5882A>G p.D1961G | Missense Mutation (SNP) | VAF 32/619 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KMT2D | c.3263C>T p.P1088L | Missense Mutation (SNP) | VAF 71/472 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KNTC1 | c.5193A>T p.K1731N | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- KRTAP10-7 | c.781A>G p.S261G | Missense Mutation (SNP) | VAF 28/598 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.161); called by muse, mutect2
- L3MBTL4 | c.989T>A p.F330Y | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.812); called by muse, mutect2
- LAMP3 | c.54T>G p.I18M | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); called by muse, mutect2
- LAP3 | c.1466A>C p.K489T | Missense Mutation (SNP) | VAF 54/412 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- LARP1B | c.2114A>C p.N705T | Missense Mutation (SNP) | VAF 26/433 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LDB3 | c.106A>C p.S36R | Missense Mutation (SNP) | VAF 19/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LILRB5 | c.328A>G p.S110G | Missense Mutation (SNP) | VAF 46/672 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LIN54 | c.1824A>C p.K608N | Missense Mutation (SNP) | VAF 20/395 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LINGO3 | c.530A>G p.E177G | Missense Mutation (SNP) | VAF 22/548 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2
- LLCFC1 | c.225A>G p.A75= (on ENST00000458732; = p.A44= on NM_178829.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 24/470 reads (5%) | called by muse, mutect2
- LMO7 | c.3607A>G p.S1203G (on ENST00000357063; = p.S884G on NM_005358.5) | Missense Mutation (SNP) | VAF 20/510 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2
- LMO7 | c.4873T>C p.C1625R (on ENST00000357063; = p.C1306R on NM_005358.5) | Missense Mutation (SNP) | VAF 29/355 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- LNX1 | c.414A>C p.K138N (on ENST00000263925 / NM_001126328.3; = p.K42N on NM_032622.2) | Missense Mutation (SNP) | VAF 16/458 reads (3%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.894); called by muse, mutect2
- LOXHD1 | c.4598A>C p.N1533T | Missense Mutation (SNP) | VAF 62/477 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- LPIN1 | c.1945T>G p.F649V | Missense Mutation (SNP) | VAF 26/534 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- LRIG2 | c.809T>G p.L270R | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- LRIG3 | c.2230T>G p.F744V | Missense Mutation (SNP) | VAF 64/393 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRIT2 | c.988T>C p.S330P | Missense Mutation (SNP) | VAF 38/558 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); called by muse, mutect2
- LRIT3 | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 21/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- LRP2 | c.6074A>C p.N2025T | Missense Mutation (SNP) | VAF 28/513 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2
- LRRC27 | c.1341A>C p.Q447H | Missense Mutation (SNP) | VAF 25/351 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- LRRC53 | c.1834A>C p.K612Q | Missense Mutation (SNP) | VAF 16/327 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.413); called by muse, mutect2
- LRRC8A | c.2374A>G p.N792D | Missense Mutation (SNP) | VAF 19/520 reads (4%) | SIFT tolerated (1); PolyPhen possibly damaging (0.503); called by muse, mutect2
- LRRC8D | c.897A>C p.E299D | Missense Mutation (SNP) | VAF 45/400 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC8E | c.335A>G p.H112R | Missense Mutation (SNP) | VAF 69/417 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LSM1 | c.402A>C p.*134Yext*12 | Nonstop Mutation (SNP) | VAF 37/226 reads (16%) | called by muse, mutect2, varscan2
- LUM | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- LY6L | c.173A>G p.E58G | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- MAB21L1 | c.14A>G p.Q5R | Missense Mutation (SNP) | VAF 21/451 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2
- MAGEB6B | c.101A>C p.K34T | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAMDC2 | c.1368A>C p.Q456H | Missense Mutation (SNP) | VAF 48/431 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MAN1C1 | c.1844T>C p.L615P | Missense Mutation (SNP) | VAF 49/371 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP1B | c.2978T>C p.V993A | Missense Mutation (SNP) | VAF 50/461 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MAP4K1 | c.431T>G p.L144R | Missense Mutation (SNP) | VAF 54/383 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- MAP4K3 | c.1207T>G p.L403V | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAP6 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 22/498 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- MAP7D2 | c.1328A>C p.E443A | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- MAP9 | c.1421A>C p.E474A | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- MAPK8IP1 | c.137A>G p.D46G | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MARCHF10 | c.1204T>G p.S402A | Missense Mutation (SNP) | VAF 42/573 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2
- MARCHF7 | c.515-1G>A p.X172_splice | Splice Site (SNP) | VAF 14/177 reads (8%) | called by muse, mutect2
- MAST4 | c.3862A>C p.N1288H (on ENST00000403625 / NM_001164664.2; = p.N1099H on NM_015183.3) | Missense Mutation (SNP) | VAF 45/414 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCF2L | c.844A>G p.K282E (on ENST00000375608; = p.K250E on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MEFV | c.1100T>G p.L367R | Missense Mutation (SNP) | VAF 77/537 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- MEGF11 | c.1994A>G p.Q665R | Missense Mutation (SNP) | VAF 73/457 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- MEGF8 | c.5878T>G p.C1960G (on ENST00000251268 / NM_001271938.2; = p.C1893G on NM_001410.3) | Missense Mutation (SNP) | VAF 34/514 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- MELK | c.869T>C p.L290P | Missense Mutation (SNP) | VAF 34/496 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- MEMO1 | c.195A>C p.Q65H | Missense Mutation (SNP) | VAF 40/342 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEPE | c.1504T>G p.F502V | Missense Mutation (SNP) | VAF 28/566 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- MGAM2 | c.3205T>G p.F1069V | Missense Mutation (SNP) | VAF 19/418 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MICAL1 | c.2324A>T p.E775V | Missense Mutation (SNP) | VAF 25/398 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, mutect2
- MMP13 | c.1131A>T p.K377N | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); called by muse, mutect2
- MORC3 | c.2776T>G p.L926V | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MORF4L1 | c.305T>C p.L102P (on ENST00000331268 / NM_206839.2; = p.L63P on NM_006791.4) | Missense Mutation (SNP) | VAF 17/420 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MPP3 | c.967+1G>A p.X323_splice | Splice Site (SNP) | VAF 20/398 reads (5%) | called by muse, mutect2
- MRAP2 | c.82T>C p.Y28H | Missense Mutation (SNP) | VAF 19/375 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MRGPRX1 | c.388T>C p.Y130H | Missense Mutation (SNP) | VAF 34/820 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- MRPL10 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 32/628 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.057); called by muse, mutect2
- MRPL11 | c.520T>G p.F174V | Missense Mutation (SNP) | VAF 39/448 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- MTF1 | c.1847A>G p.Q616R | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MTMR3 | c.1457T>C p.L486P | Missense Mutation (SNP) | VAF 19/364 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2
- MUC16 | c.41254T>G p.F13752V | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2
- MUC16 | c.35932T>G p.L11978V | Missense Mutation (SNP) | VAF 48/415 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- MUC4 | c.13928A>T p.Q4643L (on ENST00000463781 / NM_018406.7; = p.Q407L on NM_004532.6) | Missense Mutation (SNP) | VAF 56/420 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MYBPC2 | c.2192T>G p.F731C | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MYCBP2 | c.10085+1G>A p.X3362_splice (on ENST00000357337; = p.X3400_splice on NM_015057.5) | Splice Site (SNP) | VAF 33/242 reads (14%) | called by muse, varscan2
- MYH1 | c.1109A>C p.K370T | Missense Mutation (SNP) | VAF 21/497 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- MYH11 | c.3596A>C p.Q1199P | Missense Mutation (SNP) | VAF 88/538 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.378); called by muse, varscan2
- MYH13 | c.5801A>G p.Q1934R | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- MYH15 | c.2237A>G p.K746R | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2
- MYH6 | c.4351T>C p.F1451L | Missense Mutation (SNP) | VAF 33/394 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2
- MYH7B | c.1565T>G p.I522S | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYH8 | c.1741T>C p.S581P | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2
- MYLK3 | c.2294T>C p.L765P | Missense Mutation (SNP) | VAF 54/388 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYLK3 | c.2099T>A p.V700D | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO5C | c.4931A>C p.K1644T | Missense Mutation (SNP) | VAF 67/491 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MZB1 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 17/336 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); called by muse, mutect2
- NADK2 | c.806T>G p.L269R (on ENST00000381937 / NM_001085411.3; = p.L106R on NM_153013.4) | Missense Mutation (SNP) | VAF 19/381 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); called by muse, mutect2
- NALCN | c.1250A>T p.E417V | Missense Mutation (SNP) | VAF 55/267 reads (21%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- NCDN | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 63/496 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- NCLN | c.1025A>T p.E342V | Missense Mutation (SNP) | VAF 40/402 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- NCOA6 | c.3812A>G p.D1271G | Missense Mutation (SNP) | VAF 37/588 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NCOA7 | c.659A>C p.K220T | Missense Mutation (SNP) | VAF 35/404 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NDST3 | c.1056A>C p.K352N | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NEB | c.3109T>C p.F1037L | Missense Mutation (SNP) | VAF 32/422 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.986); called by muse, mutect2
- NF1 | c.6925T>A p.S2309T (on ENST00000358273 / NM_001042492.3; = p.S2288T on NM_000267.3) | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- NFIB | c.763T>G p.S255A | Missense Mutation (SNP) | VAF 25/473 reads (5%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.685); called by muse, mutect2
- NFKB1 | c.2223A>G p.A741= (on ENST00000394820 / NM_001382627.1; = p.A742= on NM_003998.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 20/298 reads (7%) | called by muse, mutect2
- NIBAN1 | c.60A>C p.K20N | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NIPAL1 | c.689A>C p.K230T | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2
- NLGN2 | c.1749A>G p.I583M | Missense Mutation (SNP) | VAF 91/545 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- NLRP8 | c.155A>G p.E52G | Missense Mutation (SNP) | VAF 23/415 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2
- NMUR2 | c.341T>G p.F114C | Missense Mutation (SNP) | VAF 20/503 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- NOL4L | c.496T>G p.F166V | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NOTCH3 | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 55/353 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- NOTCH4 | c.4623A>C p.E1541D | Missense Mutation (SNP) | VAF 30/422 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.076); called by muse, mutect2
- NPAS2 | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 69/429 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- NPR3 | c.1382A>C p.E461A | Missense Mutation (SNP) | VAF 34/474 reads (7%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.709); called by muse, mutect2
- NPTN | c.416A>G p.Q139R | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- NR1H4 | c.1317A>C p.E439D (on ENST00000551379 / NM_001206993.2; = p.E425D on NM_005123.4) | Missense Mutation (SNP) | VAF 67/475 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, varscan2
- NRBP2 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 57/455 reads (13%) | called by muse, mutect2, varscan2
- NRDE2 | c.2092T>C p.Y698H | Missense Mutation (SNP) | VAF 58/516 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, varscan2
- NT5DC3 | c.881A>C p.K294T | Missense Mutation (SNP) | VAF 31/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- NTM | c.934+4A>G | Splice Region (SNP) | VAF 22/434 reads (5%) | called by muse, mutect2
- NUP133 | c.3339T>G p.I1113M | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- NUP205 | c.2555T>G p.L852R | Missense Mutation (SNP) | VAF 46/516 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- NUP205 | c.4414A>C p.S1472R | Missense Mutation (SNP) | VAF 26/621 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); called by muse, mutect2
- NUP210 | c.5399T>C p.F1800S | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); called by muse, mutect2
- NXPE3 | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 17/382 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- NYAP1 | c.1760A>G p.K587R | Missense Mutation (SNP) | VAF 163/623 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- OBSL1 | c.3662T>A p.L1221H | Missense Mutation (SNP) | VAF 27/661 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OLIG3 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 24/526 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR1G1 | c.598T>G p.F200V | Missense Mutation (SNP) | VAF 50/427 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- OR2T3 | c.856T>C p.F286L | Missense Mutation (SNP) | VAF 43/1196 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- OR4K17 | c.181T>C p.F61L | Missense Mutation (SNP) | VAF 18/450 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2
- OR4K17 | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 18/333 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2
- OR51A4 | c.495A>C p.L165F | Missense Mutation (SNP) | VAF 46/668 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR51I1 | c.596T>G p.I199S | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR51I1 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 48/430 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.028); called by mutect2, varscan2
- OR51T1 | c.122T>C p.L41P | Missense Mutation (SNP) | VAF 67/449 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- OR52E5 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 45/490 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2
- OR5AC2 | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 50/473 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, varscan2
- OR5K4 | c.147T>G p.I49M | Missense Mutation (SNP) | VAF 25/427 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR9Q1 | c.827T>G p.L276R | Missense Mutation (SNP) | VAF 47/373 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, varscan2
- PAICS | c.794A>G p.Q265R | Missense Mutation (SNP) | VAF 51/322 reads (16%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- PAK1 | c.1095A>T p.Q365H | Missense Mutation (SNP) | VAF 33/342 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PAM | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAMR1 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 67/371 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- PAX4 | c.578A>G p.Q193R | Missense Mutation (SNP) | VAF 35/502 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); called by muse, mutect2
- PCDH1 | c.1217A>G p.E406G | Missense Mutation (SNP) | VAF 30/596 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH10 | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 52/429 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCMTD2 | c.1030A>G p.S344G | Missense Mutation (SNP) | VAF 38/778 reads (5%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2
- PDE3B | c.2932G>A p.D978N | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDZD3 | c.1260T>C p.V420= (on ENST00000531114; = p.V340= on NM_024791.4) | Splice Region (SNP) | VAF 41/358 reads (11%) | called by muse, mutect2
- PHC2 | c.1793A>C p.K598T (on ENST00000257118 / NM_198040.2; = p.K63T on NM_004427.4) | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- PHKA1 | c.1588T>G p.F530V | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PINLYP | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 62/455 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIP | c.207A>C p.K69N | Missense Mutation (SNP) | VAF 37/392 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2
- PIP4P1 | c.482T>G p.L161R | Missense Mutation (SNP) | VAF 57/439 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- PIP5K1B | c.478A>C p.N160H | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.345); called by muse, mutect2
- PKD1 | c.1848A>C p.A616= | Splice Region (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- PKD1L3 | c.4981T>A p.L1661M | Missense Mutation (SNP) | VAF 51/371 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, varscan2
- PKD1L3 | c.3713T>C p.L1238P | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PLEC | c.11096A>G p.E3699G (on ENST00000322810 / NM_201380.4; = p.E3589G on NM_000445.5) | Missense Mutation (SNP) | VAF 67/504 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2
- PLEKHA8 | c.241A>T p.R81* | Nonsense Mutation (SNP) | VAF 64/513 reads (12%) | called by muse, mutect2, varscan2
- PLSCR4 | c.707A>C p.Q236P | Missense Mutation (SNP) | VAF 24/564 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- PLXNA1 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 30/644 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- PLXNC1 | c.2993A>G p.E998G | Missense Mutation (SNP) | VAF 23/346 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- POLQ | c.1415T>G p.L472R | Missense Mutation (SNP) | VAF 25/438 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- POLR1B | c.818A>C p.E273A | Missense Mutation (SNP) | VAF 37/466 reads (8%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.755); called by muse, mutect2
- POLR2D | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 38/600 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- POLR3A | c.2942A>T p.K981M | Missense Mutation (SNP) | VAF 45/290 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- POT1 | c.1633A>G p.T545A | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.057); called by muse, mutect2
- PPID | c.830T>C p.L277P | Missense Mutation (SNP) | VAF 43/421 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAME | c.1093A>C p.S365R | Missense Mutation (SNP) | VAF 30/716 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.099); called by muse, mutect2
- PRDM5 | c.838A>G p.K280E | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- PREX2 | c.1340T>C p.V447A | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by muse, mutect2
- PRICKLE2 | c.2141A>G p.E714G (on ENST00000295902; = p.E658G on NM_198859.4) | Missense Mutation (SNP) | VAF 69/481 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRMT9 | c.1514A>C p.N505T | Missense Mutation (SNP) | VAF 60/413 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRPF4B | c.829T>A p.S277T | Missense Mutation (SNP) | VAF 39/389 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- PRPF8 | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 52/361 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR14 | c.865T>C p.S289P | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRR14L | c.5567T>G p.F1856C | Missense Mutation (SNP) | VAF 50/554 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- PRR32 | c.638T>C p.F213S | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PRRC2C | c.1522G>A p.E508K (on ENST00000367742; = p.E506K on NM_015172.4) | Missense Mutation (SNP) | VAF 51/476 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRRT4 | c.1196T>C p.L399P | Missense Mutation (SNP) | VAF 69/670 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PRSS23 | c.1004A>C p.K335T | Missense Mutation (SNP) | VAF 28/513 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSMB11 | c.231T>G p.C77W | Missense Mutation (SNP) | VAF 21/492 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PSME4 | c.2450T>C p.V817A | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- PTCHD4 | c.1705A>C p.S569R | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.288); called by muse, mutect2
- PTP4A3 | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 50/584 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- PTPN21 | c.2706A>T p.R902S | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- PTPRC | c.116A>C p.K39T | Missense Mutation (SNP) | VAF 36/377 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PTPRQ | c.5616A>C p.E1872D (on ENST00000616559; = p.E1830D on NM_001145026.2) | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PTPRS | c.5197T>C p.S1733P | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRS | c.4468A>C p.M1490L | Missense Mutation (SNP) | VAF 34/411 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- PURG | c.82A>G p.S28G | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); called by mutect2, varscan2
- PVT1 | n.903+4A>C | Splice Region (SNP) | VAF 32/424 reads (8%) | called by muse, mutect2
- RAD51AP2 | c.2739T>G p.N913K | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RAET1L | c.527A>C p.K176T | Missense Mutation (SNP) | VAF 34/866 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.444); called by muse, mutect2
- RALA | c.332T>G p.I111S | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RALGAPA2 | c.1568T>G p.F523C | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- RAPGEF2 | c.2370T>G p.H790Q | Missense Mutation (SNP) | VAF 23/395 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.349); called by muse, mutect2
- RASGRF1 | c.2938A>G p.I980V | Missense Mutation (SNP) | VAF 57/383 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RBM15 | c.305A>G p.K102R | Missense Mutation (SNP) | VAF 58/572 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2
- RBM20 | c.2630A>G p.D877G | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RBM43 | c.787A>G p.S263G | Missense Mutation (SNP) | VAF 24/477 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- RBM44 | c.82A>C p.K28Q (on ENST00000611254; = p.K662Q on NM_001080504.2) | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- RCBTB1 | c.1530A>T p.Q510H | Missense Mutation (SNP) | VAF 26/616 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2
- REPS2 | c.920A>C p.K307T | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFC1 | c.1088A>C p.K363T | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); called by muse, mutect2
- RFPL2 | c.518A>T p.K173M | Missense Mutation (SNP) | VAF 50/472 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- RFPL4B | c.212T>G p.L71R | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.173); called by muse, mutect2
- RGMA | c.326T>G p.L109R | Missense Mutation (SNP) | VAF 60/474 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIC1 | c.2866A>T p.R956W | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RIPOR1 | c.1640G>A p.G547D (on ENST00000379312 / NM_001193522.2; = p.G543D on NM_024519.4) | Missense Mutation (SNP) | VAF 38/630 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- RNF213 | c.3876T>G p.D1292E | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.488); called by muse, mutect2
- RNF43 | c.1489T>C p.F497L | Missense Mutation (SNP) | VAF 32/510 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- RO60 | c.1385A>C p.D462A | Missense Mutation (SNP) | VAF 26/512 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ROBO1 | c.238T>C p.S80P | Missense Mutation (SNP) | VAF 54/410 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPS6KC1 | c.2476T>C p.S826P | Missense Mutation (SNP) | VAF 56/401 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RRP9 | c.563A>T p.K188M | Missense Mutation (SNP) | VAF 51/450 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RSC1A1 | c.1715T>A p.F572Y | Missense Mutation (SNP) | VAF 28/442 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- RSL1D1 | c.1344A>C p.K448N | Missense Mutation (SNP) | VAF 68/550 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- RSL24D1 | c.343A>C p.N115H | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.224); called by muse, mutect2
- RSPH4A | c.798A>C p.K266N | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- RSPH4A | c.1155A>C p.E385D | Missense Mutation (SNP) | VAF 62/472 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- RTTN | c.5404T>A p.L1802M | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- RUSC2 | c.1743A>T p.Q581H | Missense Mutation (SNP) | VAF 24/635 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- RXYLT1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2
- SACS | c.10477A>G p.K3493E | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2
- SACS | c.1154A>C p.K385T | Missense Mutation (SNP) | VAF 38/494 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2
- SAP130 | c.244T>G p.S82A | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, mutect2
- SBSN | c.215T>G p.L72R | Missense Mutation (SNP) | VAF 64/543 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCAF11 | c.3716T>A p.L1239* | Nonsense Mutation (SNP) | VAF 46/628 reads (7%) | called by muse, mutect2
- SCN11A | c.3690T>G p.N1230K | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2
- SCN11A | c.799T>G p.F267V | Missense Mutation (SNP) | VAF 34/512 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2
- SCN1A | c.1135A>C p.M379L | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SCN3A | c.4739T>A p.L1580H | Missense Mutation (SNP) | VAF 46/550 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN5A | c.5857A>G p.S1953G (on ENST00000333535 / NM_198056.3; = p.S1952G on NM_000335.5) | Missense Mutation (SNP) | VAF 38/584 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- SCN5A | c.4690A>G p.N1564D (on ENST00000333535 / NM_198056.3; = p.N1563D on NM_000335.5) | Missense Mutation (SNP) | VAF 27/697 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- SCN5A | c.2024A>G p.E675G | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2
- SCUBE3 | c.881A>C p.N294T | Missense Mutation (SNP) | VAF 38/554 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SDK2 | c.4661T>A p.L1554H | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- SEMA4G | c.108G>A p.M36I | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- SEMA6D | c.2743A>C p.M915L (on ENST00000316364 / NM_153618.2; = p.M853L on NM_020858.2) | Missense Mutation (SNP) | VAF 28/534 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SERPING1 | c.1262T>C p.F421S | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SETD2 | c.5456A>C p.K1819T | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- SETD2 | c.4117A>T p.S1373C | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SEZ6L | c.1404T>G p.S468R | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, mutect2
- SEZ6L2 | c.1042T>C p.S348P (on ENST00000308713 / NM_001114099.3; = p.S278P on NM_012410.4) | Missense Mutation (SNP) | VAF 34/373 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.043); called by muse, mutect2
- SGPL1 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SGPP2 | c.399A>C p.Q133H | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIPA1L1 | c.1786A>G p.T596A | Missense Mutation (SNP) | VAF 20/389 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.344); called by muse, mutect2
- SLC12A5 | c.130A>G p.N44D (on ENST00000454036 / NM_001134771.2; = p.N21D on NM_020708.5) | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- SLC12A8 | c.884T>G p.L295R | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- SLC22A18 | c.641A>C p.Q214P | Missense Mutation (SNP) | VAF 76/440 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC24A4 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 56/378 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A24 | c.451T>G p.F151V | Missense Mutation (SNP) | VAF 19/264 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- SLC26A2 | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 87/459 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, varscan2
- SLC35G3 | c.643T>C p.F215L | Missense Mutation (SNP) | VAF 39/720 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.325); called by muse, mutect2
- SLC38A8 | c.955T>G p.S319A | Missense Mutation (SNP) | VAF 17/407 reads (4%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.688); called by muse, mutect2
- SLC4A4 | c.410A>C p.K137T (on ENST00000264485 / NM_001098484.3; = p.K93T on NM_003759.4) | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC4A4 | c.2564T>C p.L855S (on ENST00000264485 / NM_001098484.3; = p.L811S on NM_003759.4) | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SLC8A3 | c.1202A>G p.D401G | Missense Mutation (SNP) | VAF 26/465 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2
- SLC9A9 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 19/352 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2
- SLCO1B1 | c.1154T>C p.I385T | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, varscan2
- SLCO2A1 | c.959T>A p.L320Q | Missense Mutation (SNP) | VAF 37/336 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by mutect2, varscan2
- SLIT2 | c.82T>C p.C28R | Missense Mutation (SNP) | VAF 33/605 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMAD1 | c.383A>T p.K128M | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); called by muse, mutect2
- SMCO1 | c.640A>C p.N214H | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.371); called by muse, mutect2
- SMIM35 | c.104A>G p.Q35R | Missense Mutation (SNP) | VAF 23/428 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.892); called by muse, mutect2
- SMPD4 | c.1811A>T p.K604I (on ENST00000409031 / NM_017951.4; = p.K575I on NM_017751.4) | Missense Mutation (SNP) | VAF 50/379 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SMYD1 | c.147T>G p.N49K | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT tolerated (0.86); PolyPhen benign (0.124); called by muse, mutect2
- SNCA | c.305A>G p.K102R | Missense Mutation (SNP) | VAF 54/664 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.406); called by muse, mutect2
- SON | c.4130A>G p.E1377G | Missense Mutation (SNP) | VAF 81/573 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA31D1 | c.2237A>G p.K746R | Missense Mutation (SNP) | VAF 80/633 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SPATC1L | c.440A>T p.K147M | Missense Mutation (SNP) | VAF 90/623 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- SPDYE1 | c.233A>C p.H78P | Missense Mutation (SNP) | VAF 54/447 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- SPEN | c.5513A>G p.K1838R | Missense Mutation (SNP) | VAF 34/549 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SPPL2C | c.692A>G p.Q231R | Missense Mutation (SNP) | VAF 104/671 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SRC | c.809T>C p.L270P | Missense Mutation (SNP) | VAF 34/652 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SRRT | c.1074del p.D359Tfs*109 | Frame Shift Del (DEL) | VAF 109/493 reads (22%) | called by mutect2, pindel, varscan2
- STARD9 | c.2030T>G p.F677C | Missense Mutation (SNP) | VAF 26/456 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2
- STK38L | c.1302A>C p.K434N | Missense Mutation (SNP) | VAF 47/360 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- STXBP5L | c.2407G>T p.V803F | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.143); called by muse, varscan2
- SVIL | c.3284A>G p.K1095R (on ENST00000355867 / NM_021738.3; = p.K669R on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/464 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SVIL | c.3052T>G p.F1018V (on ENST00000355867 / NM_021738.3; = p.F592V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/650 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2
- TBC1D15 | c.1453C>T p.H485Y | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- TBC1D23 | c.1945A>C p.K649Q (on ENST00000394144 / NM_001199198.3; = p.K634Q on NM_018309.5) | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- TBC1D30 | c.1530T>C p.T510= (on ENST00000542120; = p.T347= on NM_015279.2 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 24/342 reads (7%) | called by muse, mutect2
- TCHH | c.1622A>G p.E541G | Missense Mutation (SNP) | VAF 56/415 reads (13%) | PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TDRD15 | c.3359T>C p.L1120P | Missense Mutation (SNP) | VAF 15/352 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TEAD2 | c.1175A>G p.Q392R | Missense Mutation (SNP) | VAF 29/479 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.266); called by muse, mutect2
- TERT | c.3373T>C p.S1125P | Missense Mutation (SNP) | VAF 27/461 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.084); called by muse, mutect2
- TERT | c.2129A>G p.K710R | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TESMIN | c.1450A>C p.I484L | Missense Mutation (SNP) | VAF 24/570 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, mutect2
- TEX26 | c.263A>C p.K88T | Missense Mutation (SNP) | VAF 27/338 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.372); called by muse, mutect2
- TEX30 | c.278T>A p.L93H | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- THBS2 | c.668A>T p.K223M | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.599); called by muse, varscan2
- THBS4 | c.194A>T p.K65M | Missense Mutation (SNP) | VAF 78/490 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- THSD7B | c.4147A>G p.T1383A (on ENST00000272643; = p.T1381A on NM_001316349.2) | Missense Mutation (SNP) | VAF 58/440 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TKTL2 | c.761A>G p.N254S | Missense Mutation (SNP) | VAF 40/624 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.01); called by muse, mutect2
- TLCD3B | c.296A>G p.K99R | Missense Mutation (SNP) | VAF 37/506 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.223); called by muse, mutect2
- TLR3 | c.1370A>C p.N457T | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2
- TMEM117 | c.170A>C p.K57T | Missense Mutation (SNP) | VAF 52/430 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM168 | c.1714A>C p.I572L | Missense Mutation (SNP) | VAF 22/536 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- TMEM181 | c.533T>G p.L178R | Missense Mutation (SNP) | VAF 21/361 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM247 | c.422A>C p.E141A | Missense Mutation (SNP) | VAF 25/541 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2
- TMEM62 | c.468T>G p.N156K | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TMEM63C | c.1787T>G p.F596C | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- TMPRSS11E | c.407A>C p.K136T | Missense Mutation (SNP) | VAF 28/405 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.257); called by muse, mutect2
- TMPRSS3 | c.947T>G p.F316C | Missense Mutation (SNP) | VAF 40/540 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- TNIP1 | c.850A>G p.S284G | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TOP3A | c.1310T>A p.I437N | Missense Mutation (SNP) | VAF 68/373 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TOPAZ1 | c.4781A>C p.E1594A | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TOPORS | c.2813A>C p.E938A | Missense Mutation (SNP) | VAF 79/495 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TPTE2 | c.143T>G p.F48C | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- TRANK1 | c.5292T>G p.Y1764* | Nonsense Mutation (SNP) | VAF 22/458 reads (5%) | called by muse, mutect2
- TRANK1 | c.3620T>G p.L1207R | Missense Mutation (SNP) | VAF 72/489 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TRIP11 | c.5840T>A p.L1947H | Missense Mutation (SNP) | VAF 35/583 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRMT11 | c.1356A>C p.K452N | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRO | c.2266G>A p.G756S | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.925); called by muse, mutect2
- TRPC6 | c.2054T>C p.L685P | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRPM8 | c.147T>G p.F49L | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2
- TRPV4 | c.1814T>G p.M605R | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC27 | c.1630C>T p.Q544* | Nonsense Mutation (SNP) | VAF 26/418 reads (6%) | called by muse, mutect2
- TTC29 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 52/481 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TTC30A | c.1777T>G p.L593V | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TTN | c.66672A>C p.R22224S (on ENST00000591111; = p.R14800S on NM_003319.4) | Missense Mutation (SNP) | VAF 52/374 reads (14%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.11260A>G p.I3754V (on ENST00000591111; = p.I3708V on NM_003319.4) | Missense Mutation (SNP) | VAF 55/503 reads (11%) | called by muse, mutect2, varscan2
- TUBA3D | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 23/418 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- TULP3 | c.725A>C p.K242T | Missense Mutation (SNP) | VAF 37/366 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUT4 | c.882A>G p.K294= | Splice Region (SNP) | VAF 68/400 reads (17%) | called by muse, varscan2
- TYK2 | c.2723T>C p.F908S | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
310 further variants in this file (62 protein-altering or splice-affecting, 209 silent, 39 other) are not listed here.
